MMRF case MMRF_2090 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eb102824-5bf4-4df3-b2a9-bfe3f9c1390c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.6 years (19,202 days); ISS stage: II; Days to last known disease status: 513 days (1.4 years); Days to last follow up: 513 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 14 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 139 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 263 days; Days to treatment end: 477 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 513 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: M Protein 8.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 397 mg/dL; Immunoglobulin G 104 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.19 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 12 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.031 mg/dL.
- Day 50 (ECOG 0): M Protein 0.9 g/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 106 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 4.13 mmol/L.
- Day 268 (ECOG 0): Hemoglobin 7.44 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3.29 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 345 (ECOG 0): Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.68 mmol/L.
- Day 429 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.73 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 513 (ECOG 0): Hemoglobin 8.31 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 208 ×10⁹/L.

Other clinical attributes
- Day -27: Weight: 81 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2090_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2090_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
